Somatic mutation profile of tumor specimen C3L-00601-02 (aliquot CPT0007600009) from CPTAC case C3L-00601, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 57.2 years (20,899 days).
Specimen C3L-00601-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1262e94d-41a0-47c5-a62d-49af31fa8040.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00601-31 (Blood Derived Normal), aliquot CPT0002900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4271791f-ab84-4e76-a82e-a862c28d9652

The open-access MAF lists 4,993 somatic variants for this specimen: 3,516 protein-altering or splice-affecting, 892 silent, 585 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,016, Silent 892, Nonsense Mutation 379, Intron 313, RNA 93, 3'UTR 78, Splice Site 61, 5'UTR 43, Splice Region 40, 5'Flank 32, 3'Flank 26, Frame Shift Ins 17.

Variants (750 of 4,993; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 27/109 reads (25%) | catalogued as rs371637724, COSV55631924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4012C>T p.Q1338* | Nonsense Mutation (SNP) | VAF 158/393 reads (40%) | hotspot (GDC flag); catalogued as rs121913327, CM930029, COSV57325971; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 49/147 reads (33%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 74/294 reads (25%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATRX | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs797044563, COSV64871348; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.7987G>A p.E2663K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80359030, COSV66459259; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- BTK | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 145/423 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs128620183, CM940199, CM950170, COSV58117568, COSV58123749; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN5 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 46/113 reads (41%) | catalogued as rs797044810, CM983859, COSV56582168; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CUBN | c.7906C>T p.R2636* | Nonsense Mutation (SNP) | VAF 145/382 reads (38%) | catalogued as rs137998687; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 124/317 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- MSH6 | c.1795G>T p.G599* | Nonsense Mutation (SNP) | VAF 167/447 reads (37%) | catalogued as rs756043669; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587783772, CM1513749, CM970999, COSV60337210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NEXN | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); catalogued as rs971313210, COSV57358805; ClinVar: likely pathogenic; called by muse, mutect2
- PAH | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 112/435 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs76687508, CM930548, COSV61018094; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 40/90 reads (44%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 54/89 reads (61%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PRKCG | c.1081A>G p.S361G | Missense Mutation (SNP) | VAF 114/478 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs121918517, CM054071, COSV54730311; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 181/497 reads (36%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 51/142 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 26/85 reads (31%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RSPH3 | c.595C>T p.R199* (on ENST00000252655; = p.R57* on NM_031924.8) | Nonsense Mutation (SNP) | VAF 55/149 reads (37%) | catalogued as rs760122351, COSV51921181; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs397516539, CM065450, CM156349, COSV63686290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SATB2 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 44/216 reads (20%) | catalogued as rs797044874, CM153271; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SETD5 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 22/410 reads (5%) | catalogued as rs1421204500, COSV56715022; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SOS1 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 179/441 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs397517180, CM070284, COSV67675939; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VPS13B | c.4411C>T p.R1471* | Nonsense Mutation (SNP) | VAF 48/184 reads (26%) | catalogued as rs386834086, CM090643, COSV62151221; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 99/291 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1463177829, COSV59384882; called by muse, mutect2, varscan2
- A4GNT | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52628738; called by muse, mutect2, varscan2
- AAAS | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 46/732 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs61739860; called by muse, mutect2
- AADACL2 | c.904C>A p.L302I | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV62931402; called by muse, mutect2, varscan2
- ABCA12 | c.6392C>T p.P2131L (on ENST00000272895 / NM_173076.3; = p.P1813L on NM_015657.3) | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs758142404, COSV99788485; called by muse, mutect2, varscan2
- ABCA13 | c.7270G>A p.A2424T | Missense Mutation (SNP) | VAF 104/274 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs1367421989, COSV71287201; called by muse, mutect2, varscan2
- ABCA13 | c.8119G>T p.D2707Y | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as rs528610620, COSV104436048, COSV99081668; called by muse, mutect2, varscan2
- ABCA3 | c.4450C>T p.R1484W | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.218); catalogued as rs1027580482; called by muse, mutect2
- ABCA6 | c.3911G>T p.R1304I | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776208870, COSV99446539; called by muse, mutect2, varscan2
- ABCA8 | c.4210C>T p.P1404S | Missense Mutation (SNP) | VAF 115/305 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1284120664; called by muse, mutect2, varscan2
- ABCA8 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs370110491; called by muse, mutect2, varscan2
- ABCA9 | c.3794G>T p.R1265I | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749474709, COSV100383217; called by muse, mutect2, varscan2
- ABCB11 | c.3278C>T p.S1093L | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1030004521, COSV99793428; called by muse, mutect2, varscan2
- ABCB4 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs746249103; called by muse, mutect2, varscan2
- ABCB5 | c.3407C>A p.S1136Y (on ENST00000404938 / NM_001163941.2; = p.S691Y on NM_178559.6) | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1004816440; called by muse, mutect2, varscan2
- ABCG2 | c.578G>T p.R193M | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1406395272; called by muse, mutect2
- AC068580.4 | c.1175C>A p.P392Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV52587161; called by muse, varscan2
- AC126283.2 | c.1439G>T p.R480I | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV67098078, COSV67099926; called by muse, varscan2
- ACBD3 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 33/398 reads (8%) | catalogued as rs781141478, COSV64730313; called by muse, mutect2
- ACO1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273311415, COSV100008813; called by muse, varscan2
- ACOX2 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 121/326 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs538107717; called by muse, mutect2, varscan2
- ACSM2B | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs150327444, COSV61657515; called by muse, mutect2, varscan2
- ACSM4 | c.1590G>T p.E530D | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs1412358684, COSV68067591, COSV68067628; called by muse, varscan2
- ADAM10 | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 124/351 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs375834613; called by muse, mutect2, varscan2
- ADAM29 | c.2009G>T p.R670I | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV100822144; called by muse, varscan2
- ADAM7 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1333012683, COSV51535711; called by muse, mutect2
- ADAM9 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 74/235 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.506); catalogued as rs1344174952, COSV65946589; called by muse, mutect2, varscan2
- ADAMTS16 | c.1148C>A p.A383D | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56978757; called by muse, mutect2
- ADAMTS20 | c.5312+1G>A p.X1771_splice | Splice Site (SNP) | VAF 22/48 reads (46%) | catalogued as rs774360431, COSV101240460; called by muse, mutect2, varscan2
- ADAMTS3 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs768336339, COSV54391795; called by muse, mutect2, varscan2
- ADAMTS7 | c.4147G>A p.A1383T | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs906389735, COSV101183029; called by muse, mutect2, varscan2
- ADAMTSL3 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 40/149 reads (27%) | catalogued as rs771154300, COSV99721988; called by muse, mutect2, varscan2
- ADAMTSL4 | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.275); catalogued as COSV99646493; called by muse, mutect2, varscan2
- ADARB2 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 134/342 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1174693400; called by muse, mutect2, varscan2
- ADCY10 | c.3099G>T p.K1033N | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.107); catalogued as COSV63240898; called by muse, mutect2, varscan2
- ADD2 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs141431061; called by muse, mutect2
- ADGB | c.2566A>G p.T856A | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1010234574; called by muse, mutect2, varscan2
- ADGRF3 | c.3095G>A p.R1032H (on ENST00000311519 / NM_001145168.1; = p.R833H on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as rs1250347432, COSV61050885, COSV61053856; called by muse, mutect2, varscan2
- ADGRG2 | c.2935G>A p.D979N (on ENST00000379869 / NM_001079858.3; = p.D976N on NM_005756.4) | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV61340211; called by muse, mutect2
- ADH1B | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 39/102 reads (38%) | catalogued as COSV59295747, COSV59297779; called by muse, mutect2, varscan2
- ADH4 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs557732938, COSV55500215; called by muse, mutect2, varscan2
- ADH7 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as rs759568380, COSV52920929; called by muse, mutect2, varscan2
- AFF4 | c.3436C>T p.R1146C | Missense Mutation (SNP) | VAF 91/266 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755303727, COSV54793041; called by muse, mutect2, varscan2
- AFG3L2 | c.2182C>T p.L728F | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as rs532751601; called by muse, mutect2, varscan2
- AFG3L2 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 57/479 reads (12%) | catalogued as COSV99301367; called by muse, mutect2, varscan2
- AFG3L2 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 120/341 reads (35%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs776352499, COSV52312899; called by muse, mutect2, varscan2
- AFP | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56925417; called by muse, mutect2, varscan2
- AFTPH | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.804); catalogued as COSV99480262; called by muse, mutect2, varscan2
- AGAP2 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs755835605; called by muse, mutect2
- AGBL5 | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs775595367, COSV59935575; called by muse, mutect2
- AGO1 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64595188; called by muse, varscan2
- AGTPBP1 | c.3539G>A p.R1180Q (on ENST00000357081 / NM_001330701.2; = p.R1140Q on NM_015239.2) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.389); catalogued as rs774787421, COSV100430313; called by mutect2, varscan2
- AGXT2 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 130/374 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.238); catalogued as rs572826520; called by muse, mutect2, varscan2
- AHCTF1 | c.1349C>T p.S450L (on ENST00000366508; = p.S424L on NM_015446.5) | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs528013816, COSV58246078; called by muse, varscan2
- AHDC1 | c.2218C>T p.R740C | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780652723; called by muse, mutect2, varscan2
- AHNAK | c.4134G>A p.W1378* | Nonsense Mutation (SNP) | VAF 77/394 reads (20%) | catalogued as COSV57204611; called by muse, mutect2, varscan2
- AHNAK2 | c.3344C>T p.A1115V | Missense Mutation (SNP) | VAF 33/408 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs112329740, COSV60906636; called by muse, mutect2
- AICDA | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 113/248 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs373061990, COSV57563722, COSV57563879; called by muse, mutect2, varscan2
- AIM2 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.172); catalogued as COSV63700286; called by muse, mutect2
- AK8 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs866414004, COSV53754993; called by muse, mutect2, varscan2
- AK9 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs148574935; called by muse, mutect2, varscan2
- AKAP3 | c.1412C>A p.S471Y | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.786); catalogued as COSV57415923; called by muse, mutect2
- AKAP6 | c.1381A>G p.K461E | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV55205367; called by muse, mutect2, varscan2
- AKAP9 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 38/458 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs864622705, COSV100662522, COSV62344491; ClinVar: uncertain significance; called by muse, mutect2
- AKR1D1 | c.858C>A p.I286= | Splice Region (SNP) | VAF 32/338 reads (9%) | catalogued as COSV54337502; called by muse, mutect2
- AL645922.1 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 27/472 reads (6%) | catalogued as rs763450579, COSV54962560; called by muse, mutect2
- AL645922.1 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 90/469 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1277447428; called by muse, mutect2, varscan2
- ALAS1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs773336919, COSV59626776; called by muse, mutect2, varscan2
- ALG11 | c.778T>C p.W260R | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs1301367744; called by muse, mutect2, varscan2
- ALG13 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 33/111 reads (30%) | catalogued as COSV52638289; called by muse, mutect2, varscan2
- ALMS1 | c.10542C>A p.F3514L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as COSV100043108, COSV52521743; called by muse, mutect2, varscan2
- ALOX5 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs373773649, COSV100979977, COSV65551797; called by muse, mutect2, varscan2
- ALPK2 | c.4330G>A p.E1444K | Missense Mutation (SNP) | VAF 109/260 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs370248466, COSV64490192; called by muse, mutect2
- ALX1 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57494362; called by muse, mutect2
- ALX4 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 32/298 reads (11%) | catalogued as rs1156752533, COSV61326517; called by muse, mutect2, varscan2
- AMER1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1157288902, COSV57656246; called by muse, mutect2, varscan2
- AMY2B | c.260G>T p.R87I | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100796441; called by muse, mutect2, varscan2
- ANK1 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 129/336 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1285981952, COSV55885216; called by muse, mutect2, varscan2
- ANK2 | c.10804C>T p.R3602* | Nonsense Mutation (SNP) | VAF 122/292 reads (42%) | catalogued as COSV52152721; called by muse, mutect2, varscan2
- ANK3 | c.7543C>A p.L2515I | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as rs1266079762, COSV55082059, COSV99781928; called by muse, varscan2
- ANKAR | c.3814C>T p.R1272C | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs145081425; called by muse, mutect2
- ANKAR | c.4070G>A p.R1357Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1376221117, COSV51461865; called by muse, mutect2, varscan2
- ANKEF1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs1056528269; called by muse, mutect2, varscan2
- ANKFN1 | c.1305G>T p.K435N | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1268228110; called by muse, mutect2
- ANKMY1 | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.173); catalogued as COSV56033611, COSV56034960; called by muse, mutect2, varscan2
- ANKMY1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 77/595 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1472021219, COSV56030432; called by muse, mutect2, varscan2
- ANKRD30B | c.2774C>A p.S925Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV57703165; called by muse, mutect2, varscan2
- ANKRD50 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 87/424 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753155406, COSV72386246; called by muse, mutect2, varscan2
- ANKRD52 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs778944625, COSV57284597; called by muse, mutect2, varscan2
- ANO4 | c.809G>T p.R270I (on ENST00000392977 / NM_001286615.2; = p.R235I on NM_178826.4) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1245505933; called by muse, mutect2, varscan2
- ANOS1 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99390804; called by muse, mutect2, varscan2
- ANXA2 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV60318953; called by muse, mutect2, varscan2
- ANXA6 | c.1794G>T p.K598N | Missense Mutation (SNP) | VAF 81/232 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62906675; called by muse, mutect2, varscan2
- AOAH | c.1663C>A p.L555M | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as rs942231604; called by muse, varscan2
- AOX1 | c.2215C>A p.L739I | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs767970704, COSV65982275; called by muse, mutect2, varscan2
- AOX1 | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373370000, COSV99057936; called by muse, mutect2, varscan2
- APBA2 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 42/617 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67105258; called by muse, mutect2
- APBB1 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs775846607, COSV54966759; called by muse, mutect2, varscan2
- APLP2 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1212536922, COSV53842237; called by muse, mutect2, varscan2
- APOB | c.11607C>A p.F3869L | Missense Mutation (SNP) | VAF 89/236 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.065); catalogued as COSV51942607, COSV51954942; called by muse, mutect2, varscan2
- APOB | c.3974C>A p.S1325Y | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV51940116; called by muse, mutect2, varscan2
- APOBEC4 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as rs753388975, COSV100426060; called by muse, mutect2, varscan2
- APOL5 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 44/145 reads (30%) | catalogued as rs568136674, COSV50767095; called by muse, mutect2, varscan2
- AQP1 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 90/361 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as COSV61266433; called by muse, mutect2, varscan2
- AR | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM970103; called by muse, mutect2, varscan2
- ARAF | c.713G>T p.S238I | Missense Mutation (SNP) | VAF 91/256 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs1187147586; called by muse, mutect2, varscan2
- ARAP2 | c.4043C>A p.S1348Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs185198158, COSV58285549; called by muse, mutect2, varscan2
- ARAP2 | c.2975G>T p.R992I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV58285009; called by muse, mutect2, varscan2
- ARFGEF3 | c.817C>A p.H273N | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99292186; called by muse, varscan2
- ARHGAP10 | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs750229345, COSV60598454; called by muse, mutect2, varscan2
- ARHGAP11A | c.1290G>T p.K430N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV64381232; called by muse, mutect2, varscan2
- ARHGAP24 | c.1715G>A p.R572H (on ENST00000395184 / NM_001025616.3; = p.R479H on NM_031305.3) | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs149024248; called by muse, mutect2
- ARHGAP25 | c.1862T>C p.V621A (on ENST00000409202 / NM_001007231.3; = p.V613A on NM_014882.3) | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54902370; called by muse, mutect2, varscan2
- ARHGAP29 | c.1865C>T p.T622M | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs901902219, CM129105; called by muse, mutect2, varscan2
- ARHGAP31 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 107/318 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.058); catalogued as COSV51796775; called by muse, mutect2, varscan2
- ARHGAP33 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs143998454; called by muse, mutect2, varscan2
- ARHGEF12 | c.2720G>A p.R907Q | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs754072463; called by muse, mutect2, varscan2
- ARHGEF25 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs147406368; called by mutect2, varscan2
- ARHGEF28 | c.1954C>T p.R652* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as rs1482499575, COSV55270057; called by muse, mutect2, varscan2
- ARHGEF33 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs1253671749; called by muse, mutect2
- ARHGEF40 | c.3358C>T p.R1120W | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777686185, COSV100069989; called by muse, mutect2, varscan2
- ARID1A | c.5481C>A p.C1827* | Nonsense Mutation (SNP) | VAF 19/156 reads (12%) | catalogued as COSV61378636; called by muse, mutect2, varscan2
- ARID2 | c.239G>T p.R80I | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100536269; called by muse, mutect2, varscan2
- ARID4A | c.3049C>T p.R1017* | Nonsense Mutation (SNP) | VAF 52/145 reads (36%) | catalogued as rs1344759651, COSV62162823; called by muse, mutect2, varscan2
- ARL6 | c.381C>A p.F127L | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.498); catalogued as COSV60117637, COSV60118364; called by muse, mutect2, varscan2
- ARPP21 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV51794552, COSV51810314; called by muse, mutect2, varscan2
- ASAH2 | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1007281285; called by muse, mutect2
- ASNS | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755078931; called by mutect2, varscan2
- ASPHD2 | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 14/201 reads (7%) | catalogued as COSV99313493; called by muse, mutect2
- ASPM | c.3098C>A p.S1033Y | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54125174; called by muse, mutect2, varscan2
- ASPN | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs146516859; called by muse, mutect2, varscan2
- ASXL3 | c.4617C>A p.F1539L | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as COSV99324555; called by muse, mutect2, varscan2
- ASXL3 | c.6697G>A p.D2233N | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99323617; called by muse, mutect2, varscan2
- ATAD2 | c.2219C>A p.S740Y | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV54877540; called by muse, mutect2, varscan2
- ATIC | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs199518893, COSV52692257; called by muse, mutect2, varscan2
- ATP10A | c.3202C>T p.R1068* | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as rs756615616, COSV63522017; called by muse, mutect2, varscan2
- ATP11B | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 12/250 reads (5%) | catalogued as COSV100018165; called by muse, mutect2
- ATP11C | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 35/104 reads (34%) | catalogued as rs867529692, COSV59560522; called by muse, mutect2, varscan2
- ATP11C | c.869C>A p.S290Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV104403930; called by muse, mutect2
- ATP13A5 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs755794261, COSV60877217; called by muse, mutect2, varscan2
- ATP6V1E2 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV60576197; called by muse, mutect2, varscan2
- ATP7A | c.1406A>C p.E469A | Missense Mutation (SNP) | VAF 125/354 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs1377636628; called by muse, mutect2, varscan2
- ATP7A | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as rs781995242, CM078711, COSV58442198; ClinVar: uncertain significance; called by muse, mutect2
- ATP8A2 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs546393054, COSV54957824; called by muse, mutect2, varscan2
- ATRNL1 | c.620+1G>A p.X207_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as rs372430190; called by muse, mutect2, varscan2
- ATRX | c.2764G>A p.D922N | Missense Mutation (SNP) | VAF 64/262 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs373581602; called by muse, varscan2
- ATXN1 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.164); catalogued as rs1462885923; called by muse, mutect2, varscan2
- AZIN2 | c.687G>T p.K229N | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99613782; called by muse, mutect2, varscan2
- B3GALT2 | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.631); catalogued as rs1210668199, COSV100813590; called by muse, mutect2, varscan2
- B3GNT8 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as rs752770011; called by muse, mutect2, varscan2
- B3GNTL1 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1224670800, COSV57948261; called by muse, mutect2, varscan2
- B4GALT6 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371621631; called by muse, mutect2, varscan2
- BAIAP2L1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765327861, COSV50057558; called by muse, mutect2, varscan2
- BAZ1A | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62410075; called by muse, mutect2, varscan2
- BBS2 | c.710G>T p.R237I | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99802773; called by muse, mutect2, varscan2
- BBS4 | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 82/569 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as rs960944955; called by muse, mutect2, varscan2
- BCLAF1 | c.827C>A p.S276Y | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62146741; called by muse, mutect2
- BCORL1 | c.3890G>A p.R1297Q | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750069944; called by muse, mutect2
- BEST1 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 86/428 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs886048428, COSV56444675, COSV99861428; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BIRC6 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70196110; called by muse, mutect2, varscan2
- BIRC6 | c.6790A>G p.N2264D | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.615); catalogued as rs770235787; called by muse, mutect2, varscan2
- BMP2 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770615288; called by muse, varscan2
- BNC1 | c.2476C>T p.R826* | Nonsense Mutation (SNP) | VAF 101/250 reads (40%) | catalogued as rs1270575850, COSV61757410; called by muse, mutect2, varscan2
- BOD1L2 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1405690189; called by muse, mutect2, varscan2
- BPIFB1 | c.1331C>A p.S444Y | Missense Mutation (SNP) | VAF 88/225 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV53608863, COSV99487608; called by muse, mutect2, varscan2
- BPIFB6 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs779003259, COSV62754699; called by muse, mutect2, varscan2
- BPIFC | c.1301T>C p.F434S | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.909); catalogued as COSV99322006; called by muse, mutect2
- BRCC3 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57463069; called by muse, mutect2, varscan2
- BRD1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 19/332 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53461826; called by muse, mutect2
- BRF2 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1476064682, COSV55103190; called by muse, mutect2, varscan2
- BRSK1 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV58667719; called by muse, varscan2
- BRWD1 | c.1708G>T p.D570Y | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1406282052, COSV60899182; called by muse, mutect2, varscan2
- BRWD3 | c.1594G>T p.D532Y | Missense Mutation (SNP) | VAF 33/359 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100956602; called by muse, mutect2
- BSN | c.4625C>T p.T1542M | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs201782083, COSV56519135; called by muse, mutect2, varscan2
- BSN | c.4828C>A p.P1610T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs769938179; called by mutect2, varscan2
- BTAF1 | c.4863+1G>T p.X1621_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV56433521; called by muse, mutect2, varscan2
- BTBD10 | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 71/259 reads (27%) | catalogued as rs752423002; called by muse, mutect2, varscan2
- BTK | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 21/202 reads (10%) | catalogued as CM950160; called by muse, mutect2, varscan2
- BTK | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 188/498 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CX163523, COSV58119602; called by muse, mutect2, varscan2
- BTN1A1 | c.664A>C p.N222H | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs780113739; called by muse, mutect2, varscan2
- BTNL2 | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV66630193; called by muse, mutect2, varscan2
- C12orf4 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as COSV99712749; called by muse, mutect2
- C12orf56 | c.1584+1G>A p.X528_splice (on ENST00000543942 / NM_001170633.2; = p.X368_splice on NM_001099676.3) | Splice Site (SNP) | VAF 24/74 reads (32%) | catalogued as rs750571502, COSV61490473; called by muse, mutect2, varscan2
- C18orf63 | c.834C>A p.F278L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV74057587; called by muse, mutect2, varscan2
- C1QC | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1185500809; called by muse, mutect2, varscan2
- C1QTNF2 | c.826G>A p.D276N (on ENST00000393975; = p.D231N on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764375956; called by muse, varscan2
- C1orf109 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs766285884, COSV63656831; called by muse, mutect2, varscan2
- C2orf16 | c.5242A>G p.R1748G | Missense Mutation (SNP) | VAF 50/738 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as rs755158554; called by muse, mutect2
- C3AR1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61736561, COSV99369192; called by muse, mutect2, varscan2
- C3orf70 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 27/324 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs756242736; called by muse, mutect2
- C4orf54 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1353578745, COSV72766678; called by muse, mutect2, varscan2
- C5AR1 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as rs770659810, COSV61892721, COSV61892949; called by muse, mutect2, varscan2
- C7 | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs780107037, COSV57474906; called by mutect2, varscan2
- C7orf33 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs775386548, COSV61022855, COSV61023427; called by muse, mutect2, varscan2
- C9 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371134723; called by muse, mutect2, varscan2
- C9 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 82/253 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749534250, COSV54674594; called by muse, mutect2, varscan2
- CACNA1A | c.5032C>T p.R1678C | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs794727558, COSV64189829, COSV64201848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1D | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 37/283 reads (13%) | catalogued as COSV55437189; called by muse, mutect2, varscan2
- CACNA1E | c.5339G>T p.R1780I | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV62385134; called by muse, mutect2, varscan2
- CACNA1F | c.2075G>T p.S692I | Missense Mutation (SNP) | VAF 144/337 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV100544600; called by muse, mutect2, varscan2
- CACNA1H | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs770827490, COSV61983719; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1I | c.4781G>A p.R1594Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1045204674, COSV100358855, COSV60816250; called by muse, mutect2
- CACUL1 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100432716, COSV60993115; called by muse, mutect2
- CADM2 | c.622G>A p.E208K (on ENST00000407528 / NM_001167674.2; = p.E210K on NM_153184.4) | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.793); catalogued as rs201652066, COSV67409614; called by muse, mutect2, varscan2
- CALCOCO1 | c.1748C>A p.S583Y | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1488795656, COSV50425619; called by muse, mutect2, varscan2
- CAMSAP2 | c.3688G>T p.E1230* (on ENST00000236925 / NM_001297707.2; = p.E1219* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 49/100 reads (49%) | catalogued as COSV52666739; called by muse, varscan2
- CAPN13 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 99/233 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.508); catalogued as rs757975134, COSV99700504; called by muse, mutect2, varscan2
- CAPS2 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs199654216, COSV60825126; called by muse, mutect2, varscan2
- CARD11 | c.1057A>G p.T353A | Missense Mutation (SNP) | VAF 131/304 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV67798606, COSV67798781; called by muse, mutect2, varscan2
- CASD1 | c.2128C>T p.L710= | Splice Region (SNP) | VAF 34/94 reads (36%) | catalogued as rs1314132898; called by muse, varscan2
- CASP10 | c.387G>T p.E129D | Missense Mutation (SNP) | VAF 147/416 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.154); catalogued as rs762663648; called by muse, varscan2
- CASP5 | c.546C>A p.I182= | Splice Region (SNP) | VAF 14/106 reads (13%) | catalogued as rs1455955135, COSV52827591; called by muse, mutect2, varscan2
- CASP7 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs965965084, COSV61881624; called by muse, mutect2, varscan2
- CATSPERE | c.1484G>T p.S495I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100835361; called by muse, mutect2
- CAVIN2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1418867937, COSV58423666; called by muse, mutect2
- CBLB | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765908020, COSV99913997; called by muse, mutect2, varscan2
- CBLL1 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.755); catalogued as rs768405085, COSV56029910, COSV99755655; called by muse, mutect2, varscan2
- CBLL2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV60368461; called by muse, mutect2, varscan2
- CBLL2 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 110/262 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs868368528, COSV60370252; called by muse, mutect2, varscan2
- CBR4 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs146775658; called by muse, mutect2, varscan2
- CCDC122 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV55708664, COSV99865881; called by muse, varscan2
- CCDC158 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV101187230; called by muse, mutect2, varscan2
- CCDC160 | c.14G>T p.R5I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs947108162, COSV100892084; called by muse, mutect2, varscan2
- CCDC168 | c.17087C>T p.A5696V | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs778324347; called by muse, mutect2, varscan2
- CCDC175 | c.385C>A p.L129I | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.05); catalogued as rs1445399946; called by muse, mutect2, varscan2
- CCDC180 | c.3303C>A p.F1101L | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV63828768; called by muse, mutect2, varscan2
- CCDC38 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs762838749, COSV60184165, COSV60185012; called by muse, mutect2, varscan2
- CCDC42 | c.495C>T p.F165= | Splice Region (SNP) | VAF 61/123 reads (50%) | catalogued as rs752538761, COSV99549780; called by muse, mutect2, varscan2
- CCDC43 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs372602870; called by muse, mutect2, varscan2
- CCDC6 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 72/360 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs983534852, COSV54057008; called by muse, mutect2, varscan2
- CCDC63 | c.996G>T p.K332N | Missense Mutation (SNP) | VAF 31/376 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs141094849, COSV57529948; called by muse, mutect2
- CCDC74A | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781396415, COSV54609605; called by muse, mutect2, varscan2
- CCDC88A | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 21/208 reads (10%) | catalogued as COSV99711120; called by muse, mutect2, varscan2
- CCN6 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs140750750, COSV57888796; ClinVar: uncertain significance; called by muse, mutect2
- CCNA1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 140/341 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765233671, COSV55220035; called by muse, mutect2, varscan2
- CCNB1IP1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 128/369 reads (35%) | SIFT tolerated, low confidence (0.44); PolyPhen probably damaging (0.981); catalogued as rs1176246517; called by muse, mutect2, varscan2
- CCSER1 | c.2167T>C p.Y723H | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100387714; called by muse, mutect2, varscan2
- CCT5 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 46/429 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs149067488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD109 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs547286744; called by muse, mutect2, varscan2
- CD163 | c.61T>G p.F21V | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.057); catalogued as COSV104418152; called by muse, mutect2
- CD163L1 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 97/286 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs779416105, COSV58016469; called by muse, mutect2, varscan2
- CD40LG | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 81/409 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs145115086, COSV65698277; ClinVar: benign; called by muse, mutect2, varscan2
- CD48 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs773326701, COSV100924337; called by muse, mutect2
- CD69 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 16/385 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV57303868; called by muse, mutect2
- CD82 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1452286030; called by muse, mutect2, varscan2
- CDC14C | c.1492G>A p.E498K (on ENST00000428251; = p.E391K on NM_152627.3) | Missense Mutation (SNP) | VAF 99/366 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs758667733; called by muse, mutect2, varscan2
- CDC23 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV67509296; called by muse, mutect2, varscan2
- CDC37 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV55767809; called by muse, mutect2
- CDH18 | c.1322G>T p.R441M | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs141966139; called by muse, mutect2, varscan2
- CDH19 | c.1215G>A p.R405= | Splice Region (SNP) | VAF 11/32 reads (34%) | catalogued as rs752113252; called by muse, mutect2, varscan2
- CDH23 | c.6742C>T p.R2248W | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs568677689, COSV56451184; called by muse, mutect2, varscan2
- CDH26 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as rs565450572; called by muse, mutect2, varscan2
- CDH3 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 181/528 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs758751065; called by muse, mutect2
- CDH3 | c.1419G>T p.K473N | Missense Mutation (SNP) | VAF 97/264 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.209); catalogued as rs747042730; called by muse, mutect2, varscan2
- CDHR3 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs200750995; called by muse, mutect2, varscan2
- CDR2 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs147381999; called by muse, mutect2, varscan2
- CDYL2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 134/346 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs1375093823, COSV73647628, COSV73647672; called by muse, mutect2, varscan2
- CEACAM21 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 170/399 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.074); catalogued as rs1039014522, COSV99494740; called by muse, mutect2, varscan2
- CEBPZOS | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs771263212, COSV99304947; called by muse, mutect2, varscan2
- CENPC | c.1776G>T p.Q592H | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV56625112; called by muse, mutect2
- CENPL | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.202); catalogued as COSV61891617; called by muse, mutect2, varscan2
- CENPN | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs528102999, COSV55141477; called by muse, varscan2
- CEP112 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 97/308 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs780421901, COSV67142461; called by muse, mutect2, varscan2
- CEP112 | c.831G>T p.Q277H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); catalogued as COSV67136090; called by muse, mutect2, varscan2
- CEP126 | c.1277C>A p.S426Y | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.136); catalogued as COSV54827461, COSV99680849; called by muse, mutect2, varscan2
- CEP152 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as rs780764155, COSV57860338; called by muse, mutect2, varscan2
- CEP350 | c.7980G>T p.Q2660H | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs968851864; called by muse, mutect2
- CEP85 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs753729078, COSV99432396; called by muse, mutect2, varscan2
- CEP95 | c.2279C>A p.S760Y | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs373296848; called by muse, mutect2, varscan2
- CERT1 | c.1921C>T p.R641* (on ENST00000405807 / NM_001130105.1; = p.R513* on NM_005713.3) | Nonsense Mutation (SNP) | VAF 22/131 reads (17%) | catalogued as COSV54656028, COSV54662581; called by muse, mutect2, varscan2
- CFAP47 | c.2420G>A p.S807N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV104400983; called by muse, mutect2, varscan2
- CFAP54 | c.5119G>T p.E1707* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV61570456, COSV61570908; called by muse, mutect2, varscan2
- CFAP54 | c.7221G>T p.E2407D | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.239); catalogued as COSV61571312; called by muse, mutect2
- CFH | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 163/479 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.18); catalogued as rs748387954, COSV62777538; called by muse, mutect2, varscan2
- CFH | c.3497C>T p.P1166L | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as CM131605; called by muse, mutect2
- CHAT | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1451392375, COSV100340285; called by muse, mutect2
- CHD1 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199778938; called by muse, mutect2, varscan2
- CHD4 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs1270212341; called by muse, mutect2, varscan2
- CHD7 | c.3656G>A p.R1219Q | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs888026080; called by muse, mutect2
- CHD8 | c.3207C>A p.F1069L (on ENST00000646647 / NM_001170629.2; = p.F790L on NM_020920.4) | Missense Mutation (SNP) | VAF 111/307 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV67870447; called by muse, mutect2, varscan2
- CHERP | c.2411C>T p.S804L | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV52225964; called by muse, mutect2
- CHIT1 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 47/520 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373659501; called by muse, mutect2
- CHML | c.1283G>T p.R428I | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761521790, COSV59363151; called by muse, mutect2, varscan2
- CHN1 | c.614T>A p.I205N | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.036); catalogued as COSV99788913; called by muse, varscan2
- CHST7 | c.495C>A p.F165L | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.388); catalogued as COSV99332817; called by muse, mutect2, varscan2
- CHSY3 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV100518716, COSV59288152; called by muse, mutect2, varscan2
- CHTOP | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.602); catalogued as rs766167372, COSV64155671; called by muse, mutect2, varscan2
- CILP2 | c.2204G>A p.R735H | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52281610; called by muse, mutect2, varscan2
- CILP2 | c.2579G>C p.R860P | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as rs762225795, COSV52273830; called by muse, mutect2, varscan2
- CLASP2 | c.2501G>T p.R834I | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56286905, COSV56290850; called by muse, mutect2
- CLCA4 | c.2312T>C p.I771T | Missense Mutation (SNP) | VAF 112/259 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV65283851; called by muse, mutect2, varscan2
- CLDN34 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 69/299 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1198913868; called by muse, mutect2, varscan2
- CLEC12B | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV100138863; called by muse, mutect2, varscan2
- CLIP4 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751580548; called by muse, mutect2, varscan2
- CLOCK | c.1427G>T p.R476I | Missense Mutation (SNP) | VAF 89/265 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV100011595; called by muse, mutect2, varscan2
- CLPP | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1313750003; called by muse, mutect2, varscan2
- CMYA5 | c.4368G>T p.E1456D | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV71407736; called by muse, mutect2, varscan2
- CNBD1 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1330613877, COSV72916988; called by muse, mutect2, varscan2
- CNNM2 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 186/441 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV63996394; called by muse, mutect2, varscan2
- CNOT1 | c.4081G>A p.D1361N | Missense Mutation (SNP) | VAF 102/294 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV55315037; called by muse, mutect2, varscan2
- CNOT1 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57774416; called by muse, mutect2
- CNPY3 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761023974, COSV65709807; ClinVar: uncertain significance; called by mutect2, varscan2
- CNTF | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV60157826; called by muse, mutect2
- CNTN1 | c.112G>T p.G38* | Nonsense Mutation (SNP) | VAF 14/222 reads (6%) | catalogued as COSV104418046, COSV61636015; called by muse, mutect2
- CNTN6 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs373263784, COSV100610795, COSV100610903; called by muse, varscan2
- CNTN6 | c.2350G>T p.E784* | Nonsense Mutation (SNP) | VAF 60/132 reads (45%) | catalogued as COSV63167981; called by muse, mutect2, varscan2
- CNTNAP2 | c.2422T>C p.S808P | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs773802167; ClinVar: uncertain significance; called by muse, varscan2
- CNTNAP2 | c.2509C>A p.L837I | Missense Mutation (SNP) | VAF 156/360 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV100664934; called by muse, varscan2
- CNTNAP2 | c.2604G>T p.E868D | Missense Mutation (SNP) | VAF 173/488 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV62211003, COSV62232879; called by muse, mutect2, varscan2
- CNTNAP5 | c.1627C>A p.L543M | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.982); catalogued as COSV101443485, COSV70489377; called by muse, mutect2
- COG6 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs775668471; called by muse, mutect2, varscan2
- COL11A1 | c.3530G>A p.G1177E | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616009; called by muse, mutect2
- COL19A1 | c.759G>T p.Q253H | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100506107, COSV59576876; called by muse, varscan2
- COL21A1 | c.2843G>T p.R948I | Missense Mutation (SNP) | VAF 166/436 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99779303; called by muse, mutect2, varscan2
- COL22A1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1236773096, COSV57329333; called by muse, mutect2, varscan2
- COL3A1 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs770157568, COSV58592902; called by muse, varscan2
- COL4A1 | c.4057G>A p.D1353N | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.934); catalogued as rs1487216157, COSV65430208; called by muse, mutect2, varscan2
- COL4A1 | c.3022G>A p.G1008R | Missense Mutation (SNP) | VAF 45/499 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM111423; called by muse, mutect2
- COL4A3 | c.4219G>T p.E1407* | Nonsense Mutation (SNP) | VAF 146/326 reads (45%) | catalogued as COSV67412540; called by muse, mutect2, varscan2
- COL4A5 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 134/352 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.867); catalogued as rs771538814, COSV60356642; called by muse, mutect2, varscan2
- COL4A6 | c.1675G>T p.D559Y | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV57874722; called by muse, mutect2, varscan2
- COL5A1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 96/295 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.15); catalogued as rs1400424598, COSV65670138; called by muse, mutect2, varscan2
- COL5A1 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 28/407 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs1420950002, COSV65665733; ClinVar: uncertain significance; called by muse, mutect2
- COL7A1 | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 173/646 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs148836522; called by muse, mutect2, varscan2
- COPA | c.3520C>T p.R1174W | Missense Mutation (SNP) | VAF 70/329 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs775562836, COSV54098154; called by muse, mutect2, varscan2
- COPB1 | c.952C>A p.L318I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV99999848; called by muse, mutect2, varscan2
- COPB1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369909236; called by muse, mutect2, varscan2
- CP | c.2930G>A p.G977E | Missense Mutation (SNP) | VAF 136/342 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs1559934957; called by muse, mutect2, varscan2
- CPA1 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 67/493 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as COSV50569412; called by muse, mutect2, varscan2
- CPLANE1 | c.225G>T p.K75N (on ENST00000425232; = p.K147N on NM_023073.3) | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV99950420; called by muse, mutect2, varscan2
- CPNE3 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1390211369, COSV99547295; called by muse, mutect2, varscan2
- CPO | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1168756117; called by muse, mutect2, varscan2
- CR2 | c.295G>T p.G99* | Nonsense Mutation (SNP) | VAF 34/188 reads (18%) | catalogued as COSV100889660, COSV65508724; called by muse, varscan2
- CRACD | c.3091G>A p.E1031K | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs1473488937; called by muse, mutect2, varscan2
- CRIM1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54864255; called by muse, mutect2, varscan2
- CROCC2 | c.1864T>C p.S622P | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1247143230; called by muse, mutect2, varscan2
- CRTAC1 | c.536C>A p.S179Y | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54005181; called by muse, mutect2, varscan2
- CRYBG3 | c.2335G>T p.D779Y | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as rs1360842354; called by muse, mutect2, varscan2
- CRYGC | c.18C>A p.F6L | Missense Mutation (SNP) | VAF 90/399 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as rs2242072; called by muse, mutect2, varscan2
- CSF2RB | c.987G>T p.E329D | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.95); catalogued as COSV53256439; called by muse, mutect2
- CSMD3 | c.7501G>T p.E2501* (on ENST00000297405 / NM_001363185.1; = p.E2397* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 23/158 reads (15%) | catalogued as COSV52293786; called by muse, mutect2, varscan2
- CSMD3 | c.6692G>A p.R2231Q (on ENST00000297405 / NM_001363185.1; = p.R2127Q on NM_052900.3) | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.6); catalogued as rs751658267, COSV52145865, COSV99832218; called by muse, mutect2
- CSMD3 | c.4568C>T p.S1523F (on ENST00000297405 / NM_001363185.1; = p.S1419F on NM_052900.3) | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV52103216, COSV52110256; called by muse, mutect2, varscan2
- CSN1S1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as rs372612450, COSV55891851; called by mutect2, varscan2
- CTCF | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 14/192 reads (7%) | catalogued as COSV50468639; called by muse, mutect2
- CTNNA2 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 102/248 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63571948; called by muse, mutect2, varscan2
- CTNNA2 | c.1671G>T p.E557D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV58163480; called by muse, mutect2, varscan2
- CTNNB1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 101/283 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1245266458, COSV62695900; called by muse, mutect2, varscan2
- CTSO | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV101467855, COSV70809895; called by muse, mutect2, varscan2
- CUL1 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1236894600, COSV57387036; called by muse, mutect2, varscan2
- CUL4B | c.1414G>T p.D472Y | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60689381, COSV60690821; called by muse, mutect2
- CWC22 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs370331309; called by muse, mutect2, varscan2
- CXorf66 | c.284C>A p.S95* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as rs770042515; called by muse, varscan2
- CYBB | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 106/296 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV66086466; called by muse, mutect2, varscan2
- CYP1A1 | c.89G>T p.R30I | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV101122322; called by muse, mutect2, varscan2
- CYP4F12 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV61174674; called by muse, varscan2
- CYP4F2 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs758521136, COSV55616510; called by muse, mutect2, varscan2
- CYP4F3 | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55414157; called by muse, mutect2, varscan2
- CYP4Z1 | c.1482G>T p.K494N | Missense Mutation (SNP) | VAF 83/173 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV61965052; called by muse, mutect2, varscan2
- CYP7A1 | c.182G>T p.R61M | Missense Mutation (SNP) | VAF 32/381 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV56963084, COSV56963173; called by muse, mutect2
- DARS2 | c.1894C>T p.R632* | Nonsense Mutation (SNP) | VAF 116/307 reads (38%) | catalogued as rs376219629; called by muse, varscan2
- DCBLD1 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 26/192 reads (14%) | catalogued as rs866727389, COSV51641759; called by muse, mutect2, varscan2
- DCLK1 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 150/397 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs775609349, COSV55212175; called by muse, varscan2
- DCLRE1B | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs766521853, COSV65812937, COSV65813369; called by muse, mutect2, varscan2
- DCXR | c.349-8G>A | Splice Region (SNP) | VAF 283/729 reads (39%) | catalogued as rs755658533; called by muse, mutect2, varscan2
- DDC | c.1067G>T p.R356I | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63564013; called by muse, mutect2
- DDI1 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 93/223 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1212172543, COSV56369168; called by muse, mutect2, varscan2
- DDX10 | c.1773A>C p.E591D | Missense Mutation (SNP) | VAF 124/298 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1176342297; called by muse, mutect2, varscan2
- DDX18 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1558732185; called by muse, mutect2, varscan2
- DDX42 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866497677, COSV63789241; called by muse, mutect2
- DDX49 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1382044270; called by muse, mutect2, varscan2
- DENND2C | c.44G>T p.R15I | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV67921539; called by muse, mutect2, varscan2
- DENND4A | c.3137G>T p.R1046I | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV101475280; called by muse, mutect2, varscan2
- DGKK | c.1919G>T p.R640L | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.095); catalogued as rs183398027; called by muse, mutect2, varscan2
- DGKK | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV65706810; called by muse, mutect2, varscan2
- DGKK | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 20/161 reads (12%) | catalogued as COSV65706395; called by muse, mutect2
- DHCR24 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 97/506 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.871); catalogued as rs201458129; called by muse, mutect2, varscan2
- DHRS13 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1472448846; called by muse, mutect2
- DHRS9 | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV59139491; called by muse, mutect2, varscan2
- DHX29 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1192164661; called by muse, mutect2, varscan2
- DHX36 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 93/284 reads (33%) | catalogued as rs1223273053, COSV57672020; called by muse, mutect2, varscan2
- DHX57 | c.2066C>T p.S689L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs1393876290; called by muse, mutect2, varscan2
- DIAPH1 | c.206G>T p.R69I | Missense Mutation (SNP) | VAF 24/379 reads (6%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.991); catalogued as COSV99526911; called by muse, mutect2
- DIAPH3 | c.2581G>A p.G861R (on ENST00000400324 / NM_001042517.2; = p.G598R on NM_030932.3) | Missense Mutation (SNP) | VAF 29/360 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368347883; called by muse, mutect2
- DICER1 | c.2831G>A p.R944Q | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as rs1555370340, COSV58615960; ClinVar: uncertain significance; called by muse, varscan2
- DIDO1 | c.3914C>T p.S1305L | Missense Mutation (SNP) | VAF 142/414 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as rs762356761, COSV56615969; called by muse, mutect2, varscan2
- DIP2B | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 123/296 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs142942647; called by muse, mutect2, varscan2
- DIPK1C | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as rs536902218; called by muse, mutect2, varscan2
- DKK3 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 81/248 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1400075472; called by muse, mutect2, varscan2
- DLEC1 | c.2938C>A p.L980I | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.305); catalogued as rs753180828, COSV100341384; called by muse, mutect2, varscan2
- DLG2 | c.278G>T p.R93I (on ENST00000650630 / NM_001351274.2; = p.R56I on NM_001142699.3) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.038); catalogued as COSV101075527; called by muse, mutect2, varscan2
- DLGAP2 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs748493812, COSV70095249, COSV70101970; called by muse, mutect2
- DLGAP4 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 85/388 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs759586146; called by muse, mutect2, varscan2
- DMAP1 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as rs1376777307; called by muse, mutect2, varscan2
- DMBT1 | c.6541G>T p.D2181Y (on ENST00000338354 / NM_001377530.1; = p.D1424Y on NM_004406.3) | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV57533595; called by muse, mutect2, varscan2
- DMD | c.7255G>T p.E2419* | Nonsense Mutation (SNP) | VAF 30/364 reads (8%) | catalogued as CM103846; called by muse, mutect2
- DMP1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs781781034, COSV56820876; called by muse, mutect2, varscan2
- DMP1 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 215/564 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as rs1481041455, COSV56819606; called by muse, mutect2, varscan2
- DMRTA1 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV57924585; called by mutect2, varscan2
- DNAH10 | c.6547G>A p.V2183I (on ENST00000409039; = p.V2122I on NM_207437.3) | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.162); catalogued as rs1317911819, COSV68996400; called by muse, mutect2, varscan2
- DNAH11 | c.4095+3G>A | Splice Region (SNP) | VAF 9/91 reads (10%) | catalogued as rs375356107; called by mutect2, varscan2
- DNAH17 | c.10143C>A p.F3381L | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV67752074; called by muse, mutect2, varscan2
- DNAH17 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); catalogued as rs868532432, COSV67750733; called by muse, mutect2, varscan2
- DNAH5 | c.9634G>T p.E3212* | Nonsense Mutation (SNP) | VAF 61/408 reads (15%) | catalogued as COSV99453602; called by muse, varscan2
- DNAH5 | c.6979G>A p.A2327T | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as rs769338611; called by muse, mutect2, varscan2
- DNAH5 | c.2480G>A p.R827H | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.572); catalogued as rs141969815; called by muse, mutect2, varscan2
- DNAH5 | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 24/470 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs887537972; called by muse, mutect2
- DNAH7 | c.5869C>T p.R1957* | Nonsense Mutation (SNP) | VAF 91/288 reads (32%) | catalogued as rs149212659, COSV56751897; called by muse, mutect2, varscan2
- DNAH8 | c.1358C>A p.S453Y | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100546559; called by muse, mutect2, varscan2
- DNAH9 | c.1780G>T p.E594* | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | catalogued as COSV52345533, COSV52373663; called by muse, mutect2
- DNAH9 | c.4288G>T p.E1430* | Nonsense Mutation (SNP) | VAF 97/553 reads (18%) | catalogued as COSV99308069; called by muse, mutect2, varscan2
- DNAH9 | c.8149G>A p.D2717N | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs944905336; called by muse, varscan2
- DNAJC11 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 38/223 reads (17%) | catalogued as rs267598695, COSV53784590; called by muse, varscan2
- DNAJC12 | c.47A>G p.Y16C | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371547184; called by muse, mutect2
- DNAJC13 | c.3674G>A p.R1225H | Missense Mutation (SNP) | VAF 97/279 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs765818290, COSV53454127; called by muse, mutect2, varscan2
- DNER | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 117/329 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as rs759503890, COSV100518998, COSV100519277; called by muse, mutect2, varscan2
- DNM1L | c.1994+2T>C p.X665_splice (on ENST00000549701 / NM_012062.5; = p.X628_splice on NM_005690.4) | Splice Site (SNP) | VAF 32/112 reads (29%) | catalogued as COSV99845654; called by muse, varscan2
- DNMBP | c.2617C>T p.H873Y | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159840724, COSV60628703; called by muse, mutect2, varscan2
- DOCK1 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as rs1057180572, COSV54759663; called by muse, mutect2
- DOCK10 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1329636844; called by muse, mutect2, varscan2
- DOCK2 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 83/243 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56947055; called by muse, mutect2, varscan2
- DOCK5 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201426822, COSV99376645; called by muse, mutect2, varscan2
- DOCK9 | c.1967C>A p.S656Y (on ENST00000376460 / NM_001366676.2; = p.S657Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.8); catalogued as COSV100240963, COSV59627432; called by muse, mutect2, varscan2
- DOK6 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs760566494, COSV66927897, COSV66935189; called by muse, mutect2, varscan2
- DOP1A | c.7075C>A p.L2359I | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as COSV52708690; called by muse, mutect2, varscan2
- DPP6 | c.584C>T p.S195F (on ENST00000377770 / NM_001364500.2; = p.S133F on NM_001936.5) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59645470; called by muse, mutect2, varscan2
- DPPA2 | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV72118351; called by muse, mutect2, varscan2
- DPYSL2 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs199869101; called by muse, mutect2, varscan2
- DRAM2 | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV54415993; called by muse, mutect2, varscan2
- DRC1 | c.1727G>A p.S576N | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV55506319; called by muse, varscan2
- DRD1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 81/168 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.098); catalogued as rs548677242, COSV67104597; called by muse, mutect2, varscan2
- DRP2 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs765750077, COSV67871426; called by muse, mutect2, varscan2
- DSC1 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs1356521849, COSV57142035; called by muse, mutect2, varscan2
- DSC3 | c.2350G>T p.G784* | Nonsense Mutation (SNP) | VAF 25/468 reads (5%) | catalogued as COSV100844761; called by muse, mutect2
- DSC3 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141252257; called by muse, varscan2
- DSPP | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 86/253 reads (34%) | catalogued as COSV99216728; called by muse, mutect2, varscan2
- DSPP | c.3337G>A p.D1113N | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs368984442; called by muse, varscan2
- DST | c.9700C>A p.L3234I | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); catalogued as COSV55017948; called by muse, mutect2, varscan2
- DST | c.6274G>T p.E2092* | Nonsense Mutation (SNP) | VAF 40/91 reads (44%) | catalogued as rs1416256967, COSV99750583; called by muse, mutect2, varscan2
- DSTN | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs138670114, COSV55712491; called by muse, varscan2
- DUSP16 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs753562199; called by muse, mutect2, varscan2
- DYNC2H1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as rs1447843742; called by muse, mutect2, varscan2
- DYNC2I1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 172/419 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1292679110; called by muse, mutect2, varscan2
- DYRK3 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs782554746, COSV100895839; called by muse, mutect2, varscan2
- DYRK4 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs371159844; called by muse, mutect2, varscan2
- DZIP1 | c.1554G>T p.Q518H (on ENST00000347108; = p.Q499H on NM_014934.5) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.687); catalogued as COSV61266909; called by muse, mutect2, varscan2
- DZIP3 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.886); catalogued as rs377325943; called by muse, mutect2, varscan2
- EBF3 | c.1060G>T p.D354Y (on ENST00000355311 / NM_001375392.1; = p.D345Y on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/279 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62481570, COSV62482140; called by muse, mutect2, varscan2
- ECT2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV51692218; called by muse, mutect2, varscan2
- EFCAB5 | c.3921G>T p.K1307N | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV57928497; called by muse, varscan2
- EFHB | c.2219G>T p.R740I | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV55549696; called by muse, mutect2, varscan2
- EFTUD2 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs759029404, COSV68184607; called by muse, mutect2, varscan2
- EIF4E | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 121/388 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs17850950, COSV55187192; called by muse, mutect2, varscan2
- EIF4EBP2 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs201115758, COSV64667397, COSV64667599; called by muse, mutect2, varscan2
- EIF4G1 | c.3094C>T p.R1032W (on ENST00000346169 / NM_198241.3; = p.R837W on NM_004953.5) | Missense Mutation (SNP) | VAF 40/396 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs778431870; called by muse, mutect2
- EIPR1 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV101182310; called by muse, mutect2
- ELF1 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53497027; called by muse, mutect2, varscan2
- ELF4 | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57452286; called by muse, mutect2, varscan2
- ELMO1 | c.365A>G p.N122S | Missense Mutation (SNP) | VAF 88/163 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.241); catalogued as rs1444333487; called by muse, mutect2, varscan2
- ELP1 | c.2746G>T p.E916* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as rs777619468, COSV101010535; called by muse, mutect2
- EMC1 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753052916, COSV100617530; called by muse, mutect2, varscan2
- EML3 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 94/242 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV99605921; called by muse, mutect2, varscan2
- EML6 | c.5323G>T p.D1775Y | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV100728134; called by muse, varscan2
- ENAM | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs373870116, COSV104432418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENKUR | c.385A>G p.R129G | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV58634106; called by muse, mutect2, varscan2
- ENOX2 | c.472C>T p.R158C (on ENST00000338144 / NM_001382520.1; = p.R129C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs150411520; called by muse, mutect2, varscan2
- ENPP1 | c.1517G>T p.R506I | Missense Mutation (SNP) | VAF 144/373 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs781158498; called by muse, mutect2, varscan2
- ENPP7 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 61/348 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as rs782491820; called by muse, mutect2, varscan2
- ENTHD1 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 91/251 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs144803190; called by muse, mutect2, varscan2
- ENTPD3 | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57195336; called by muse, mutect2, varscan2
- EPG5 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1455631275, COSV56352125; called by muse, mutect2, varscan2
- EPHA3 | c.682G>T p.G228W | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60706153, COSV60731778; called by muse, mutect2, varscan2
- EPN1 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 139/381 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1169596692, COSV50036719; called by muse, mutect2, varscan2
- EPRS1 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 16/144 reads (11%) | catalogued as COSV100859234; called by muse, varscan2
- ERC2 | c.1855C>T p.R619* | Nonsense Mutation (SNP) | VAF 27/100 reads (27%) | catalogued as rs774899210; called by muse, mutect2, varscan2
- ERC2 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs373620783, COSV104384435; called by muse, mutect2, varscan2
- ERCC2 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 140/356 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.152); catalogued as rs776313922, COSV55540691, COSV55543495; called by muse, mutect2, varscan2
- ERCC6L | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339227994, COSV57819781; called by muse, varscan2
- ERCC6L2 | c.2836C>T p.R946* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as rs1290453614; called by muse, mutect2, varscan2
- ERMAP | c.919C>A p.L307I | Missense Mutation (SNP) | VAF 70/436 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); catalogued as rs770765997, COSV60274209; called by muse, mutect2, varscan2
- ERO1B | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 99/257 reads (39%) | catalogued as COSV51595213; called by muse, mutect2, varscan2
- ERV3-1 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 19/171 reads (11%) | catalogued as COSV99276046; called by muse, mutect2, varscan2
- ERVFRD-1 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs768463887, COSV65369528; called by muse, mutect2, varscan2
- ERVV-1 | c.1283C>T p.T428M | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as rs1422300294, COSV74082619, COSV74083334; called by muse, mutect2, varscan2
- ESF1 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 131/372 reads (35%) | catalogued as rs746366462; called by muse, mutect2, varscan2
- ESS2 | c.676T>G p.Y226D | Missense Mutation (SNP) | VAF 99/247 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs947942799, COSV99350679; called by muse, mutect2, varscan2
- EVI5 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs773623075, COSV64830053; called by muse, mutect2, varscan2
- EVX2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 59/417 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1476865244, COSV57963611; called by muse, mutect2, varscan2
- EXOSC7 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs144475793; called by muse, mutect2
- EYA4 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 59/520 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as rs184768806, COSV62047699; called by muse, mutect2, varscan2
- F11R | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755819660; called by muse, mutect2, varscan2
- F13A1 | c.1597G>T p.D533Y | Missense Mutation (SNP) | VAF 180/494 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1376318084, COSV53560558, COSV53567691; called by muse, mutect2, varscan2
- FAF1 | c.1032-1G>T p.X344_splice | Splice Site (SNP) | VAF 29/93 reads (31%) | catalogued as rs1434688055, COSV65638229; called by muse, mutect2, varscan2
- FAIM2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs201425199, COSV57740700; called by muse, mutect2, varscan2
- FAM107B | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 50/185 reads (27%) | catalogued as rs998048468; called by muse, mutect2, varscan2
- FAM111B | c.1269G>A p.M423I | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV59113895; called by muse, mutect2, varscan2
- FAM13A | c.2896C>T p.R966* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as rs751043687; called by muse, mutect2, varscan2
- FAM149B1 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs774376072; called by muse, mutect2, varscan2
- FAM160A1 | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.929); catalogued as COSV70708773; called by muse, mutect2
- FAM20C | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1042913138; called by muse, mutect2, varscan2
- FAM214A | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs549552771, COSV55923805; called by muse, mutect2, varscan2
- FAM241B | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs373550235; called by muse, mutect2
- FAM3D | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs368657516, COSV62558505; called by muse, mutect2, varscan2
- FAM47C | c.2783C>A p.S928Y | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.933); catalogued as COSV63728714; called by muse, mutect2, varscan2
- FAM71A | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs759769000, COSV54235312; called by muse, mutect2, varscan2
- FAM71A | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762346683; called by muse, mutect2, varscan2
- FAM71F1 | c.65G>T p.R22I | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV59374977; called by muse, mutect2, varscan2
- FAM83H | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 235/654 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs779195206, COSV101186938; called by muse, mutect2, varscan2
- FANCB | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1569082475, COSV60760068; called by muse, mutect2, varscan2
- FARP1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.073); catalogued as rs1337642800, COSV100129967; called by muse, mutect2
- FASTKD1 | c.2213G>T p.R738I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV71624187; called by muse, mutect2, varscan2
- FASTKD1 | c.751A>G p.R251G | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1350326503; called by muse, mutect2
- FAT1 | c.13124C>T p.S4375L | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs769928509, COSV71672134; called by muse, mutect2, varscan2
- FAT2 | c.5383G>T p.E1795* | Nonsense Mutation (SNP) | VAF 44/119 reads (37%) | catalogued as COSV55815197, COSV55829946; called by muse, mutect2, varscan2
- FAT3 | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 33/168 reads (20%) | catalogued as rs1230731830, COSV53074844; called by muse, mutect2, varscan2
- FAT3 | c.7723C>A p.L2575I | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV53158336; called by muse, mutect2
- FAT3 | c.8020C>A p.L2674I | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs974657946; called by muse, mutect2, varscan2
- FAT4 | c.14861C>A p.S4954Y | Missense Mutation (SNP) | VAF 20/257 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV100628728, COSV58687122; called by muse, mutect2
- FBN1 | c.5548C>T p.R1850C | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs750720912, COSV57312210; called by muse, mutect2, varscan2
- FBXO11 | c.1625C>A p.S542Y (on ENST00000403359 / NM_001190274.2; = p.S458Y on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV57024529; called by muse, mutect2, varscan2
- FBXO30 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs777720532, COSV52790385; called by muse, mutect2, varscan2
- FBXO38 | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 11/116 reads (9%) | catalogued as rs865970485, COSV57027138; called by muse, mutect2
- FBXO45 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 45/150 reads (30%) | catalogued as COSV61146273; called by muse, mutect2, varscan2
- FCGR2A | c.674C>T p.A225V (on ENST00000271450 / NM_001136219.3; = p.A224V on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs199502630, COSV54839792; called by muse, mutect2, varscan2
- FCN2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs369954653; called by muse, mutect2, varscan2
- FEM1C | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.117); catalogued as rs376838268; called by muse, mutect2, varscan2
- FER1L6 | c.2492A>G p.H831R | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276363887; called by muse, mutect2, varscan2
- FGA | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1208077350, COSV57392810; called by muse, mutect2, varscan2
- FGD3 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.035); catalogued as rs200204136; called by muse, mutect2, varscan2
- FGD5 | c.3095C>T p.A1032V | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758570732, COSV53240556; called by muse, mutect2, varscan2
- FGF13 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.905); catalogued as COSV65432774; called by muse, mutect2, varscan2
- FGF14 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 95/418 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.873); catalogued as rs745581655; called by muse, mutect2, varscan2
- FIGN | c.1229C>A p.S410* | Nonsense Mutation (SNP) | VAF 81/181 reads (45%) | catalogued as COSV60764134; called by muse, mutect2, varscan2
- FIGNL1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1054523452, COSV63553137, COSV63553932; called by muse, mutect2, varscan2
- FKBP15 | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 120/305 reads (39%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs758349654; called by muse, mutect2, varscan2
- FLG | c.11719C>T p.R3907C | Missense Mutation (SNP) | VAF 61/632 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as rs765242559, COSV64240646; called by muse, mutect2
- FLG | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 195/502 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776936174, COSV64243974, COSV64246021; called by muse, mutect2, varscan2
- FLG2 | c.1220C>A p.S407Y | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV66167788; called by muse, mutect2, varscan2
- FLT1 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1004788109, COSV56722755; called by muse, mutect2, varscan2
- FLT3 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 94/280 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs200841206, COSV54056851; called by muse, varscan2
- FN1 | c.6668G>A p.R2223Q (on ENST00000359671 / NM_001365524.2; = p.R2192Q on NM_002026.4) | Missense Mutation (SNP) | VAF 22/377 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs889502429, COSV60551035; called by muse, mutect2
- FNTA | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs563410957, COSV56491197; called by muse, mutect2, varscan2
- FOXJ3 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV62362329; called by muse, mutect2, varscan2
- FRAS1 | c.3901G>A p.D1301N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs369945274; called by muse, mutect2, varscan2
- FRG2C | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 167/525 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1156667983; called by muse, mutect2, varscan2
- FRMD8 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs772538469, COSV58212953; called by muse, mutect2, varscan2
- FSIP2 | c.10702C>A p.L3568I | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1318884834; called by muse, mutect2, varscan2
- FUCA1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs774539460; called by muse, mutect2, varscan2
- FUNDC2 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as COSV64269790, COSV99055241; called by muse, mutect2, varscan2
- FUT8 | c.1417C>T p.R473* (on ENST00000360689 / NM_001371534.1; = p.R310* on NM_004480.4) | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | catalogued as COSV61281308; called by muse, mutect2, varscan2
- FXR2 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 20/261 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51519493; called by muse, mutect2
- FYB2 | c.1546G>T p.E516* | Nonsense Mutation (SNP) | VAF 9/100 reads (9%) | catalogued as COSV58584285; called by muse, mutect2
- GAB4 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.302); catalogued as COSV68753319, COSV68755238; called by muse, mutect2, varscan2
- GABBR2 | c.792C>A p.F264L | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as COSV52299257; called by muse, mutect2
- GABRA1 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV50102247; called by muse, mutect2, varscan2
- GABRB1 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV54974215; called by muse, mutect2
- GALNT1 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 12/286 reads (4%) | catalogued as COSV52451451; called by muse, mutect2
- GALNT8 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 136/385 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs151313517; called by muse, mutect2, varscan2
- GAN | c.1062G>A p.W354* | Nonsense Mutation (SNP) | VAF 144/394 reads (37%) | catalogued as rs748632070; called by muse, varscan2
- GAPDHS | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 42/112 reads (38%) | catalogued as rs756867170; called by muse, mutect2, varscan2
- GAPVD1 | c.3985G>A p.A1329T (on ENST00000394104; = p.A1338T on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 161/337 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs143403966; called by muse, mutect2, varscan2
- GAS7 | c.557C>T p.T186M (on ENST00000432992 / NM_201433.2; = p.T46M on NM_003644.3) | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.306); catalogued as rs763337191, COSV60443417; called by muse, mutect2, varscan2
- GATA6 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 109/358 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs978211774, COSV52527047; called by muse, mutect2, varscan2
- GCC2 | c.2851G>T p.E951* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV59180089; called by mutect2, varscan2
- GCLM | c.422A>C p.E141A | Missense Mutation (SNP) | VAF 94/238 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as COSV64686779; called by muse, mutect2, varscan2
- GCNT7 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs904292740, COSV99196534; called by muse, mutect2, varscan2
- GDI1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 168/451 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557198952, COSV99341131; called by muse, mutect2, varscan2
- GDPD4 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs922359069; called by muse, mutect2, varscan2
- GDPD4 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60019904; called by muse, mutect2, varscan2
- GGT6 | c.776G>A p.R259H (on ENST00000574154 / NM_001122890.3; = p.R227H on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs372855031; called by muse, mutect2, varscan2
- GHDC | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs148046976; called by muse, mutect2, varscan2
- GIPC2 | c.92G>A p.S31N | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54574691; called by muse, mutect2, varscan2
- GLA | c.453C>A p.Y151* | Nonsense Mutation (SNP) | VAF 112/253 reads (44%) | catalogued as rs869312305, CM051066, CM138946; called by muse, mutect2, varscan2
- GLI1 | c.1483C>A p.L495I | Missense Mutation (SNP) | VAF 127/457 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.354); catalogued as rs12578516, COSV57368420; called by muse, mutect2, varscan2
- GLI3 | c.4193C>T p.P1398L | Missense Mutation (SNP) | VAF 362/944 reads (38%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs749600708, COSV67892747; called by muse, mutect2, varscan2
- GLI3 | c.1613G>T p.R538I | Missense Mutation (SNP) | VAF 41/427 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101230130; called by muse, mutect2
- GLRX3 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as rs188360612, COSV58692365; called by muse, mutect2, varscan2
- GLYAT | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1231437794; called by muse, mutect2, varscan2
- GNPTAB | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1294971636; called by muse, mutect2, varscan2
- GOLGA8S | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as rs980797488; called by muse, mutect2, varscan2
- GOLIM4 | c.2078G>T p.R693I | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs767456229; called by muse, mutect2, varscan2
- GPAT4 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs755071830, COSV67841928; called by muse, mutect2
- GPATCH1 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as rs372282579; called by muse, mutect2
- GPCPD1 | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV66830200; called by muse, mutect2, varscan2
- GPIHBP1 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 15/276 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58209519; called by muse, mutect2
- GPR12 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101198034; called by muse, mutect2, varscan2
- GPR139 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1346374230; called by muse, mutect2, varscan2
- GPR149 | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454335036; called by mutect2, varscan2
- GPR22 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as rs1417817242, COSV51750378; called by muse, mutect2, varscan2
- GPR89A | c.369C>A p.F123L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs782343564; called by mutect2, varscan2
- GPRASP2 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100176929; called by muse, varscan2
- GPSM2 | c.1433C>A p.S478Y | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as rs377461910; called by muse, mutect2, varscan2
- GREB1 | c.4129G>A p.E1377K | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372140002; called by muse, mutect2, varscan2
- GREB1L | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 19/150 reads (13%) | catalogued as COSV52553378; called by muse, mutect2, varscan2
- GRIA1 | c.2333A>G p.N778S | Missense Mutation (SNP) | VAF 75/262 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV99598579; called by muse, mutect2, varscan2
- GRIN3A | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 38/387 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62457253; called by muse, mutect2, varscan2
- GRK3 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60794949; called by muse, mutect2, varscan2
- GRK3 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as rs146517167; called by muse, mutect2, varscan2
- GRM7 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV63142159, COSV63148872; called by muse, mutect2, varscan2
- GSTM3 | c.426C>A p.F142L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs754925377; called by muse, varscan2
- GSTO1 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 191/476 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1173648582; called by muse, mutect2, varscan2
- GTDC1 | c.994del p.S332Qfs*94 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as COSV53988993; called by mutect2, pindel, varscan2
- GUCY2F | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV99485131; called by muse, mutect2, varscan2
- GUF1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs767862235, COSV55782156; called by muse, mutect2, varscan2
- HCAR1 | c.533A>G p.D178G | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs748060410; called by muse, mutect2, varscan2
- HCN1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 169/442 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV57495742; called by muse, mutect2, varscan2
- HDAC9 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV101286771; called by muse, mutect2, varscan2
- HEATR5B | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV51852538; called by muse, mutect2, varscan2
- HECTD1 | c.7112G>A p.R2371H | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs771005504, COSV67947893; called by muse, mutect2, varscan2
- HECTD4 | c.8974G>A p.E2992K | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as rs776041555, COSV66395837; called by muse, mutect2, varscan2
- HECW1 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67833752; called by muse, mutect2, varscan2
- HECW2 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.45); catalogued as rs761027745, COSV99647389; called by muse, mutect2, varscan2
- HEG1 | c.1590C>T p.I530= | Splice Region (SNP) | VAF 18/82 reads (22%) | catalogued as rs202024429, COSV60764528; called by muse, mutect2, varscan2
- HERC2 | c.14161C>T p.R4721C | Missense Mutation (SNP) | VAF 44/390 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767159251, COSV55338284; called by muse, mutect2, varscan2
- HERC2 | c.13358C>T p.S4453L | Missense Mutation (SNP) | VAF 37/700 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs776359705, COSV55316185; called by muse, mutect2
- HERC6 | c.2740-1G>T p.X914_splice | Splice Site (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99986250; called by muse, mutect2, varscan2
- HFM1 | c.2011C>T p.R671* | Nonsense Mutation (SNP) | VAF 31/116 reads (27%) | catalogued as rs1302736891, COSV54026308; called by muse, mutect2, varscan2
- HIVEP1 | c.4307A>G p.N1436S | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV65103563; called by muse, mutect2
- HIVEP3 | c.5284C>T p.R1762C | Missense Mutation (SNP) | VAF 84/483 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56018925, COSV56019117; called by muse, mutect2, varscan2
- HK3 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs780995517, COSV52840218; called by muse, mutect2, varscan2
- HLA-A | c.252G>T p.W84C | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CD024042, COSV65145283, COSV65147007; called by muse, mutect2, varscan2
- HLCS | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV60795427; called by muse, mutect2, varscan2
- HLCS | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 69/689 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs148426470; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMCN1 | c.8387C>A p.S2796Y | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV99623565; called by muse, mutect2
- HMCN2 | c.14489A>G p.H4830R | Missense Mutation (SNP) | VAF 110/318 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs1425581740; called by muse, mutect2, varscan2
- HMSD | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs201288276; called by muse, varscan2
- HOOK1 | c.1931G>T p.R644I | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.703); catalogued as rs1559063799; called by muse, mutect2, varscan2
- HOOK2 | c.1640+7C>T | Splice Region (SNP) | VAF 77/244 reads (32%) | catalogued as rs1403889306; called by muse, mutect2, varscan2
- HOXB8 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs1408687410; called by muse, mutect2, varscan2
- HOXD10 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 293/761 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs779956928; called by muse, mutect2, varscan2
- HPDL | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs866717640; called by muse, mutect2, varscan2
- HPF1 | c.737-7C>A | Splice Region (SNP) | VAF 35/121 reads (29%) | catalogued as rs761535771; called by muse, mutect2, varscan2
- HPGD | c.218-1G>T p.X73_splice | Splice Site (SNP) | VAF 21/46 reads (46%) | catalogued as rs1166031576; called by muse, mutect2, varscan2
- HPS3 | c.510C>A p.F170L | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1036366561; called by muse, mutect2, varscan2
- HRH3 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs267606041, COSV58047691; called by muse, mutect2, varscan2
- HSD11B2 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 70/643 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs978078233, COSV52099255; called by muse, mutect2, varscan2
- HTATIP2 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 108/278 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs772920011; called by muse, mutect2, varscan2
- HTR1A | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 188/566 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1452211745, COSV100109233; called by muse, mutect2, varscan2
- HTR1A | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 197/473 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108984; called by muse, mutect2, varscan2
- HTR2C | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868979642; called by muse, mutect2
- HTR6 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 113/258 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53872972; called by muse, mutect2, varscan2
- HUWE1 | c.7972C>T p.L2658F | Missense Mutation (SNP) | VAF 87/230 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53339002, COSV53355628; called by muse, mutect2, varscan2
- HUWE1 | c.4948C>T p.R1650* | Nonsense Mutation (SNP) | VAF 81/369 reads (22%) | catalogued as COSV99472220; called by muse, mutect2, varscan2
- HYOU1 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs377216245; called by muse, mutect2, varscan2
- IARS2 | c.1353G>T p.K451N | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs760797075, COSV100228605; called by muse, mutect2, varscan2
- IBTK | c.3664G>A p.D1222N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs753509381; called by muse, mutect2
- IBTK | c.2753G>A p.G918D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100090536; called by muse, mutect2, varscan2
- ICA1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs745319774, COSV55576622, COSV55577556; called by muse, mutect2, varscan2
- IFFO1 | c.1311C>A p.F437L (on ENST00000396840 / NM_001330324.2; = p.F440L on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100350891; called by muse, mutect2, varscan2
- IFI35 | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55896872; called by muse, mutect2, varscan2
- IFIT3 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1341809117, COSV51078536; called by muse, mutect2
- IFNGR1 | c.1136C>A p.S379Y | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV62992261, COSV62992380; called by muse, mutect2
- IFNW1 | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV66522254; called by muse, mutect2, varscan2
- IGDCC3 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs759024595, COSV60078817; called by muse, mutect2, varscan2
- IGDCC4 | c.2774C>T p.A925V | Missense Mutation (SNP) | VAF 123/330 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1409411725, COSV61539500; called by muse, mutect2, varscan2
- IGF1R | c.2398C>T p.R800C | Missense Mutation (SNP) | VAF 25/315 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1318014146, COSV99153072; called by muse, mutect2
- IGF2BP1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs1364176184, COSV51731262; called by muse, mutect2, varscan2
- IGF2BP1 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 96/207 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as COSV51733073; called by muse, mutect2, varscan2
- IGF2BP1 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs753711889, COSV51735571; called by muse, mutect2, varscan2
- IGHE | c.1048T>G p.F350V | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781996638; called by muse, mutect2, varscan2
- IGKV1D-42 | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1393851414; called by muse, mutect2, varscan2
- IGLV2-14 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 43/542 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.397); catalogued as rs776748279; called by muse, mutect2
- IGLV3-10 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 68/397 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs369446978; called by muse, mutect2, varscan2
- IGSF1 | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.205); catalogued as rs199926984, COSV100811767; called by muse, mutect2, varscan2
- IGSF10 | c.4097C>A p.S1366Y | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0.088); catalogued as COSV56788605; called by muse, mutect2, varscan2
- IGSF11 | c.806G>T p.R269I (on ENST00000393775 / NM_001015887.3; = p.R268I on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1262124985, COSV100678001, COSV61174575; called by muse, mutect2, varscan2
- IGSF22 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.636); catalogued as rs768755167, COSV60039224; called by muse, mutect2
- IGSF9B | c.2657A>G p.Y886C | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58070302; called by muse, mutect2, varscan2
- IKZF1 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 121/394 reads (31%) | catalogued as COSV58787619; called by muse, mutect2, varscan2
- IL13RA2 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV54563961; called by muse, mutect2, varscan2
- IL16 | c.2525G>T p.R842I (on ENST00000302987 / NM_172217.5; = p.R141I on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs370198430, COSV57264730; called by muse, mutect2, varscan2
- IL17RB | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs767442896; called by muse, mutect2, varscan2
- IL1RAP | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.186); catalogued as rs376392541; called by muse, mutect2, varscan2
- IL5 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as rs201223432, COSV51504888; called by muse, mutect2, varscan2
- IMPG1 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as rs371337067; called by muse, mutect2, varscan2
- INO80 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1286730374, COSV104423253; called by muse, mutect2, varscan2
- INPP4B | c.1160G>T p.R387I | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs866217456; called by muse, mutect2, varscan2
- INPP5D | c.2174T>C p.V725A (on ENST00000445964 / NM_001017915.3; = p.V724A on NM_005541.5) | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.024); catalogued as rs760927030; called by muse, mutect2
- INPP5F | c.1717G>T p.D573Y | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100740248; called by muse, mutect2
- INTS6L | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 102/236 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs782069427, COSV66084074; called by muse, mutect2, varscan2
- INTS9 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV101273797; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1238C>A p.S413Y (on ENST00000485419 / NM_001197113.1; = p.S337Y on NM_014575.3) | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61841103; called by muse, mutect2, varscan2
- IQSEC3 | c.949C>T p.R317C (on ENST00000538872 / NM_001170738.2; = p.R14C on NM_015232.1) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1414854106, COSV58288346; called by muse, mutect2, varscan2
- IRAK3 | c.1193C>A p.S398* | Nonsense Mutation (SNP) | VAF 290/356 reads (81%) | catalogued as COSV54161079; called by muse, mutect2, varscan2
- IREB2 | c.2879G>A p.R960Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375120202; called by muse, mutect2, varscan2
- IRF4 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 87/267 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as rs781586995, COSV66705021, COSV66706054; called by muse, mutect2, varscan2
- IRF8 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1347366121; called by muse, mutect2
- IRS2 | c.2944G>A p.D982N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1159921146; called by muse, mutect2
- IRS4 | c.1628A>G p.N543S | Missense Mutation (SNP) | VAF 39/441 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV100929572; called by muse, mutect2
- ITGA8 | c.2216C>A p.S739Y | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as COSV100959906, COSV65226089; called by muse, mutect2, varscan2
- ITIH2 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs778895451, COSV64432929; called by muse, mutect2
- ITIH6 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.018); catalogued as rs368927944; called by muse, varscan2
- JADE3 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs373596462; called by muse, mutect2
- JAK1 | c.1649-1G>A p.X550_splice | Splice Site (SNP) | VAF 55/126 reads (44%) | catalogued as COSV61095813; called by muse, mutect2, varscan2
- JAK1 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 67/186 reads (36%) | catalogued as COSV61087251; called by muse, mutect2, varscan2
- JAKMIP1 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.32); catalogued as rs765708383, COSV51532503; called by muse, mutect2, varscan2
- JAKMIP2 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 89/242 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.731); catalogued as COSV54609716; called by muse, mutect2, varscan2
- JCAD | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 150/343 reads (44%) | catalogued as rs762905747, COSV64760643; called by muse, mutect2, varscan2
- JMJD1C | c.3071G>A p.R1024Q | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.17); catalogued as rs748085239, COSV59513778; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.899); catalogued as rs768787592, COSV59828839; called by muse, mutect2, varscan2
- JMY | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); catalogued as rs1160010461, COSV68659219; called by muse, mutect2, varscan2
- JPH1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 124/336 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749838028, COSV60608697; called by muse, mutect2, varscan2
- KAT2B | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 104/279 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1205273470, COSV55434569; called by muse, varscan2
- KAT5 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 107/283 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs1230831693, COSV100383994; called by muse, mutect2, varscan2
- KAT6A | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 29/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55905132; called by muse, mutect2
- KCNA6 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 175/462 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV54974531; called by muse, mutect2, varscan2
- KCNE5 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1455260841, COSV64508587; called by muse, mutect2, varscan2
- KCNF1 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs1357532034, COSV54464136, COSV54465168; called by muse, mutect2, varscan2
- KCNG1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 33/589 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1386260978, COSV65368626; called by muse, mutect2
- KCNG3 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV60150617; called by muse, mutect2, varscan2
- KCNH6 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1370937590; called by muse, mutect2, varscan2
- KCNIP3 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs756024630; called by muse, mutect2, varscan2
- KCNJ2 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 111/271 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs375330016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNMA1 | c.2381C>A p.P794H (on ENST00000286628 / NM_001161352.2; = p.P736H on NM_002247.4) | Missense Mutation (SNP) | VAF 24/578 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV54241337; called by muse, mutect2
- KCNT1 | c.827C>T p.A276V (on ENST00000488444; = p.A295V on NM_020822.3) | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as rs1272987725; called by muse, mutect2, varscan2
- KCNV1 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as COSV52084541, COSV99819212; called by muse, mutect2, varscan2
- KCP | c.782G>A p.R261H (on ENST00000620378; = p.R318H on NM_001366122.1) | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.817); catalogued as rs750277714; called by muse, mutect2, varscan2
- KCTD16 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as rs1554080499, COSV72577387; called by muse, mutect2, varscan2
- KCTD8 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1418262119, COSV63597388; called by muse, mutect2, varscan2
- KDM2B | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV65640102; called by muse, mutect2, varscan2
- KDM4C | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101185306; called by muse, mutect2, varscan2
- KDM5A | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs1237979376; called by muse, mutect2, varscan2
- KDR | c.527G>T p.R176I | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV99817309; called by muse, mutect2, varscan2
4,243 further variants in this file (2,766 protein-altering or splice-affecting, 892 silent, 585 other) are not listed here.
